Gene-level copy-number profile of tumor specimen TCGA-BA-4078-01A from TCGA case TCGA-BA-4078, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 83.4 years (30,480 days).
Specimen TCGA-BA-4078-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.06d88660-f2c2-4f13-88a1-87638504ab1a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-4078-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e9d54c3-7c1e-4564-afcf-843869ac0ab7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 22,553; copy number 2: 33,698; copy number 3: 1,168; copy number 4: 1,576; copy number 5: 741; copy number 6: 18; copy number 12: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-4078-01A-01D-1432-01): tumor purity 0.86, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 816 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:184,725,013–198,222,513, 304 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:68,980,021–71,629,421, 75 genes, copy number 6–12 (broad region; genes not listed).
- chr20:87,250–21,266,465, 404 genes, copy number 5 (broad region; genes not listed).
- chr20:38,419,638–39,663,552, 33 genes, copy number 5: SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1.

Autosomal genes at a single copy (total copy number 1): 20,189. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
